Somatic mutation profile of tumor specimen C3L-07221-01 (aliquot CPT0450750006) from CPTAC case C3L-07221, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 61.9 years (22,617 days).
Specimen C3L-07221-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ae3bae-d98f-4bb9-8d07-2e555d6599c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07221-31 (Blood Derived Normal), aliquot CPT0450840002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3c88d89-f25b-46bf-b514-1671facfa0d2

The open-access MAF lists 107 somatic variants for this specimen: 71 protein-altering or splice-affecting, 33 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 65, Silent 33, Splice Region 2, Intron 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 254/510 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACTRT2 | c.34G>T p.V12L | Missense Mutation (SNP) | VAF 191/613 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.306); catalogued as COSV65759606; called by muse, mutect2, varscan2
- ADCY10 | c.2026G>A p.V676I | Missense Mutation (SNP) | VAF 66/379 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs576877531, COSV63241547; called by muse, mutect2, varscan2
- AGRN | c.2468G>A p.C823Y | Missense Mutation (SNP) | VAF 667/1809 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1319685575; called by muse, mutect2, varscan2
- AP2M1 | c.708C>T p.S236= | Splice Region (SNP) | VAF 113/673 reads (17%) | catalogued as rs767715842; called by muse, mutect2, varscan2
- APOBEC1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 93/415 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.664); catalogued as rs1340514921; called by muse, mutect2, varscan2
- ATP8B2 | c.3556G>A p.A1186T (on ENST00000672630; = p.A1153T on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 271/1418 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); catalogued as rs763479110; called by muse, mutect2, varscan2
- B3GNTL1 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 396/1656 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs776022363; called by muse, mutect2, varscan2
- B4GALNT4 | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 160/696 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs769844806; called by muse, mutect2
- CCDC85A | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 219/801 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752700528, COSV101339442, COSV68151326; called by muse, mutect2, varscan2
- CD163L1 | c.3029G>A p.C1010Y | Missense Mutation (SNP) | VAF 73/336 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV58018679; called by muse, mutect2, varscan2
- CR1 | c.2374C>A p.P792T | Missense Mutation (SNP) | VAF 200/625 reads (32%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.991); catalogued as rs1276305457; called by muse, mutect2, varscan2
- CROCC | c.4264G>A p.V1422M | Missense Mutation (SNP) | VAF 86/1384 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs1033993667; called by muse, mutect2
- CYTH1 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 244/417 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as rs369357942; called by muse, mutect2, varscan2
- DOCK10 | c.5938G>A p.E1980K | Missense Mutation (SNP) | VAF 185/715 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375646049; called by muse, mutect2, varscan2
- ERICH3 | c.2783C>T p.S928L | Missense Mutation (SNP) | VAF 188/731 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs754456981, COSV58605032; called by muse, mutect2, varscan2
- FEZF2 | c.956C>T p.T319M | Missense Mutation (SNP) | VAF 87/708 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51864089; called by muse, mutect2, varscan2
- FOXA3 | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 254/833 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145277260; called by muse, mutect2, varscan2
- FRMD4A | c.2912G>A p.S971N | Missense Mutation (SNP) | VAF 208/1000 reads (21%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.075); catalogued as rs1012681461; called by muse, mutect2, varscan2
- FYN | c.430A>G p.I144V | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs1306312823; called by muse, varscan2
- HECA | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 61/608 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs747226950, COSV62768381; called by muse, mutect2, varscan2
- HECTD1 | c.3836G>A p.R1279H | Missense Mutation (SNP) | VAF 116/3394 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201513517; called by muse, mutect2
- HPN | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 137/1188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772106863; called by muse, mutect2, varscan2
- JAKMIP1 | c.2351G>A p.R784H | Missense Mutation (SNP) | VAF 172/586 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557871910, COSV101290894; called by muse, mutect2, varscan2
- JPH1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 957/1887 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.532); catalogued as rs748452859, COSV60608792; called by muse, mutect2, varscan2
- MAGEC1 | c.2333C>T p.P778L | Missense Mutation (SNP) | VAF 137/290 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.713); catalogued as rs1405478745; called by muse, mutect2, varscan2
- MYOCD | c.1253T>C p.I418T | Missense Mutation (SNP) | VAF 106/500 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1484513971; called by muse, mutect2, varscan2
- NBEA | c.7864C>T p.R2622* | Nonsense Mutation (SNP) | VAF 185/651 reads (28%) | catalogued as COSV59785030; called by muse, mutect2, varscan2
- NCAM2 | c.132G>A p.A44= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as rs942523925, COSV53086652, COSV53101523; called by muse, mutect2, varscan2
- NWD1 | c.2798C>T p.T933M | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as rs144463947; called by muse, mutect2, varscan2
- OR10H1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 759/993 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs758904258; called by muse, mutect2, varscan2
- OR6P1 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 122/415 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as rs1212940382; called by muse, mutect2, varscan2
- PCDHA3 | c.1720G>A p.G574S | Missense Mutation (SNP) | VAF 187/1112 reads (17%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.006); catalogued as COSV63545732; called by muse, mutect2, varscan2
- PDHA2 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 136/496 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1192544011, COSV54778931; called by muse, mutect2, varscan2
- PKD1 | c.6955G>A p.G2319R | Missense Mutation (SNP) | VAF 389/779 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs749129863; called by muse, mutect2, varscan2
- POLH | c.1816G>A p.A606T | Missense Mutation (SNP) | VAF 51/590 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs571269991; called by muse, mutect2
- SCN3B | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 117/582 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV54797904; called by muse, mutect2, varscan2
- SIRPG | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 101/645 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as rs777710856, COSV53810965; called by muse, mutect2, varscan2
- TBX18 | c.1546G>A p.G516S | Missense Mutation (SNP) | VAF 78/352 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs375591537, COSV63738059; called by muse, mutect2, varscan2
- TCHHL1 | c.1223G>A p.R408H | Missense Mutation (SNP) | VAF 191/428 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs754236943, COSV64286786; called by muse, mutect2, varscan2
- ZNF141 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs1436341302, COSV104383376; called by muse, mutect2, varscan2
- ZNF729 | c.2041A>G p.K681E | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs879059197, COSV62602337; called by muse, varscan2
- ADAMTSL2 | c.680_682+7del p.X227_splice | Splice Site (DEL) | VAF 114/380 reads (30%) | called by mutect2, varscan2
- AKAP6 | c.3334G>T p.G1112* | Nonsense Mutation (SNP) | VAF 13/275 reads (5%) | called by muse, mutect2
- ALDH16A1 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 371/714 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP4 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 110/1012 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- ATG9A | c.2089G>A p.V697M | Missense Mutation (SNP) | VAF 284/504 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- CABS1 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 104/175 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CADPS2 | c.2489A>T p.Q830L | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A3 | c.7888A>C p.T2630P | Missense Mutation (SNP) | VAF 121/626 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH10 | c.10997G>A p.G3666E (on ENST00000409039; = p.G3605E on NM_207437.3) | Missense Mutation (SNP) | VAF 272/1030 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GTPBP3 | c.724C>G p.R242G | Missense Mutation (SNP) | VAF 121/1147 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- IL1RAP | c.1046A>C p.Q349P | Missense Mutation (SNP) | VAF 385/678 reads (57%) | SIFT tolerated (0.1); PolyPhen benign (0.327); called by muse, mutect2, varscan2
- IQCN | c.872C>G p.A291G | Missense Mutation (SNP) | VAF 115/1199 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2
- JPH2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 1217/2249 reads (54%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL34 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2
- KLHL6 | c.569A>T p.K190M | Missense Mutation (SNP) | VAF 25/773 reads (3%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); called by muse, mutect2
- LIG1 | c.316T>A p.S106T | Missense Mutation (SNP) | VAF 236/389 reads (61%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.024); called by mutect2, varscan2
- MMP13 | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.1439C>A p.T480K | Missense Mutation (SNP) | VAF 196/424 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NAA35 | c.1967A>G p.Y656C | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR11H2 | c.587C>A p.A196D (on ENST00000556246; = p.A207D on NM_001197287.1) | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0.082); called by mutect2, varscan2
- PHF2 | c.1848G>A p.M616I | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- PLEKHG3 | c.2288A>G p.E763G (on ENST00000394691; = p.E819G on NM_001308147.2) | Missense Mutation (SNP) | VAF 93/774 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- RSBN1L | c.2355T>A p.N785K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, varscan2
- SFRP1 | c.731A>G p.K244R | Missense Mutation (SNP) | VAF 161/755 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SKOR1 | c.2273T>C p.L758P | Missense Mutation (SNP) | VAF 261/838 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.731); called by muse, varscan2
- SYDE2 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 80/881 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.101); called by muse, mutect2
- TCEAL5 | c.577G>A p.G193R | Missense Mutation (SNP) | VAF 191/342 reads (56%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TNFAIP2 | c.1640del p.Q547Rfs*66 | Frame Shift Del (DEL) | VAF 115/644 reads (18%) | called by mutect2, varscan2
- ZFPM1 | c.2385C>G p.I795M | Missense Mutation (SNP) | VAF 94/893 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.393); called by mutect2, varscan2
- ASXL2 | c.1677T>C p.V559= | Silent (SNP) | VAF 22/404 reads (5%) | called by muse, mutect2
- CLDN4 | c.36G>T p.A12= | Silent (SNP) | VAF 178/913 reads (19%) | called by muse, mutect2, varscan2
- COL22A1 | c.486G>A p.A162= | Silent (SNP) | VAF 402/2107 reads (19%) | catalogued as rs781713813, COSV57330268; called by muse, mutect2, varscan2
- DACH2 | c.174C>T p.G58= | Silent (SNP) | VAF 215/367 reads (59%) | catalogued as rs771754414, COSV64162009; called by muse, mutect2, varscan2
- DBX2 | c.450G>A p.A150= | Silent (SNP) | VAF 202/823 reads (25%) | catalogued as rs372280888; called by muse, mutect2, varscan2
- DPF3 | c.582C>T p.H194= | Silent (SNP) | VAF 222/706 reads (31%) | catalogued as rs200602274; called by muse, mutect2, varscan2
- DYSF | c.1989C>T p.S663= | Silent (SNP) | VAF 101/348 reads (29%) | called by muse, mutect2, varscan2
- ELP6 | c.468G>A p.A156= | Silent (SNP) | VAF 177/674 reads (26%) | catalogued as rs376912609; called by muse, mutect2, varscan2
- EPHB2 | c.2259C>T p.L753= (on ENST00000400191 / NM_001309193.2; = p.L754= on NM_004442.7) | Silent (SNP) | VAF 173/607 reads (29%) | catalogued as rs368213597, COSV65863757; called by muse, mutect2, varscan2
- FARS2 | c.597C>A p.L199= | Silent (SNP) | VAF 187/353 reads (53%) | called by muse, mutect2, varscan2
- FBF1 | c.2127C>T p.H709= (on ENST00000586717; = p.H723= on NM_001319193.1) | Silent (SNP) | VAF 151/726 reads (21%) | catalogued as rs1367237835; called by muse, mutect2, varscan2
- FNDC1 | c.54G>A p.A18= | Silent (SNP) | VAF 211/828 reads (25%) | called by muse, mutect2, varscan2
- GABRB1 | c.1143G>A p.S381= | Silent (SNP) | VAF 223/877 reads (25%) | catalogued as rs1228057063, COSV54986199; called by muse, mutect2, varscan2
- IKZF1 | c.123G>A p.S41= | Silent (SNP) | VAF 470/876 reads (54%) | catalogued as rs373934387; called by muse, mutect2, varscan2
- ISLR2 | c.1098G>A p.T366= | Silent (SNP) | VAF 299/925 reads (32%) | catalogued as rs747242170; called by muse, mutect2, varscan2
- JAKMIP1 | c.1125G>A p.A375= | Silent (SNP) | VAF 111/452 reads (25%) | catalogued as rs150623866; called by muse, mutect2, varscan2
- KCNMB1 | c.55C>T p.L19= | Silent (SNP) | VAF 165/513 reads (32%) | called by muse, mutect2, varscan2
- KLHDC7B | c.1458C>T p.S486= (on ENST00000395676; = p.S1127= on NM_138433.5) | Silent (SNP) | VAF 286/750 reads (38%) | catalogued as rs763221894; called by muse, mutect2, varscan2
- KLHL3 | c.339C>T p.I113= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs764364392, COSV59051183; called by muse, mutect2, varscan2
- LAMA2 | c.4992C>T p.T1664= | Silent (SNP) | VAF 59/355 reads (17%) | catalogued as rs143078882; ClinVar: likely benign; called by muse, mutect2, varscan2
- LCE1C | c.144C>T p.S48= | Silent (SNP) | VAF 258/1160 reads (22%) | catalogued as rs747442143, COSV100908448; called by muse, mutect2, varscan2
- LMOD3 | c.1017G>A p.T339= | Silent (SNP) | VAF 107/342 reads (31%) | catalogued as rs766552225; called by muse, varscan2
- MAGEC2 | c.675C>T p.P225= | Silent (SNP) | VAF 225/429 reads (52%) | catalogued as rs1213757650, COSV55999175, COSV99910072; called by muse, mutect2, varscan2
- MPPED1 | c.843C>G p.V281= | Silent (SNP) | VAF 93/392 reads (24%) | called by muse, mutect2, varscan2
- NEURL4 | c.1671C>T p.S557= | Silent (SNP) | VAF 197/594 reads (33%) | called by muse, mutect2, varscan2
- NEUROD2 | c.796C>A p.R266= | Silent (SNP) | VAF 8658/8880 reads (98%) | catalogued as rs934633734; called by muse, mutect2, varscan2
- NPAP1 | c.522C>T p.D174= | Silent (SNP) | VAF 289/548 reads (53%) | catalogued as rs368120585, COSV100274980; called by muse, mutect2, varscan2
- NRXN3 | c.2905C>T p.L969= (on ENST00000335750 / NM_001330195.2; = p.L596= on NM_004796.6) | Silent (SNP) | VAF 117/384 reads (30%) | called by muse, mutect2, varscan2
- PMEPA1 | c.426C>T p.H142= | Silent (SNP) | VAF 952/1879 reads (51%) | catalogued as rs761414024, COSV55694947; called by muse, mutect2, varscan2
- STAB1 | c.5307C>T p.A1769= | Silent (SNP) | VAF 243/969 reads (25%) | catalogued as rs145377358; called by muse, mutect2, varscan2
- TIMMDC1 | c.121C>A p.R41= | Silent (SNP) | VAF 181/674 reads (27%) | catalogued as COSV51787613; called by muse, mutect2, varscan2
- TLL2 | c.1380C>T p.Y460= | Silent (SNP) | VAF 52/642 reads (8%) | catalogued as rs756984555; called by muse, mutect2
- ZNF521 | c.2643C>T p.T881= | Silent (SNP) | VAF 143/566 reads (25%) | catalogued as rs1411393598, COSV64124140; called by muse, mutect2, varscan2
- CDH23 | c.3369+332G>C | Intron (SNP) | VAF 182/681 reads (27%) | called by muse, mutect2, varscan2
- PDE4D | c.456-140847C>G | Intron (SNP) | VAF 95/278 reads (34%) | called by muse, mutect2, varscan2
- ZFP14 | chr19:36331503 G>A | 3'Flank (SNP) | VAF 22/544 reads (4%) | catalogued as rs1201524789; called by muse, mutect2
